Somatic mutation profile of tumor specimen 0DN1DG from CCDI case PBCBEA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.9 years (4,705 days).
Specimen 0DN1DG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0e20748-d5fd-4674-b273-3549df7057b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1BB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4da28b6c-5cf3-4763-9910-e0068347e241

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, 3'UTR 3, Nonsense Mutation 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPRV1 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 258/550 reads (47%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV100208528; called by muse, mutect2, varscan2
- MET | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 197/435 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs587778443, COSV99041950; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 250/544 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ALCAM | c.1732A>T p.N578Y | Missense Mutation (SNP) | VAF 243/584 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- BZW1 | c.104_105del p.C35Yfs*7 | Frame Shift Del (DEL) | VAF 122/341 reads (36%) | called by mutect2, pindel, varscan2
- CLEC14A | c.568T>A p.L190M | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP5 | c.2046C>A p.C682* | Nonsense Mutation (SNP) | VAF 260/593 reads (44%) | called by muse, mutect2, varscan2
- ETV5 | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 131/328 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by mutect2, varscan2
- KPRP | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGR | c.2490T>G p.I830M | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC8A1 | c.1828G>C p.V610L | Missense Mutation (SNP) | VAF 209/477 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CCR6 | c.588C>G p.V196= | Silent (SNP) | VAF 172/362 reads (48%) | catalogued as COSV100551189; called by muse, mutect2, varscan2
- ALPL | c.*56C>T | 3'UTR (SNP) | VAF 101/202 reads (50%) | called by muse, mutect2, varscan2
- HTR1F | c.*37del | 3'UTR (DEL) | VAF 62/180 reads (34%) | catalogued as rs773619514; called by mutect2, pindel, varscan2
- HTR1F | c.*34T>G | 3'UTR (SNP) | VAF 68/156 reads (44%) | called by mutect2, varscan2
